Surgical pathology report (de-identified scan), TCGA case TCGA-55-7727, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7727-01A (Primary Tumor).

[page 1 of 6]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - J). LUNG, LEFT UPPER LOBE, AND ASSOCIATED WEDGE WITH REGIONAL LYMPH NODES (N6, N10L, N11L, N5, N9L, N7), WEDGE RESECTION, LOBECTOMY, AND REGIONAL LYMPHADENECTOMY:
- ADENOCARCINOMA, GRADE 2 (MODERATELY DIFFERENTIATED)
- Tumor measures 2.0 cm in greatest dimension.
- MARGIN STATUS: NEGATIVE.
- Closest margin (bronchial margin) is 4.6cm from tumor.
- 6/22 REGIONAL LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA (PERIBRONCHIAL AND PARA-AORTIC)
- VISCERAL PLEURA NOT INVOLVED BY TUMOR.
- LYMPHOVASCULAR INVASION IDENTIFIED.
- PERINEURAL INVASION IDENTIFIED.

PATHOLOGIC TUMOR STAGING SUMMARY:

Histologic type and grade: Adenocarcinoma, grade 2 (moderately differentiated).

Primary tumor: pT1a.

Regional lymph nodes: pN2. (6/22; peribronchial and para-aortic positive).

Distant metastasis: pMX.

Pathologic stage: IIIA.

Margin status: R0.

Lymphovascular invasion: Identified.

Perineural invasion: Identified.

COMMENT: Immunohistochemical staining for cytokeratin-OSCAR on block B4 shows two lymph nodes positive for metastatic carcinoma.

Immunohistochemical staining of the tumor on block A4 shows positive staining for TTF-1, Napsin-A, and MOC-31. Calretinin shows very rare and light staining. Staining is

[page 2 of 6]
FINAL SURGICAL PATHOLOGY REPORT

negative for CK5/6, Villin, CDX2, PSAP, and Ber-EP4. These results support the diagnosis of adenocarcinoma of the lung.

[page 3 of 6]
Procedure:	Wedge resection and lobectomy with lymphadenectomy.
Specimen type:	Lung, upper lobe, with associated lymph nodes.
Specimen laterality:	Left.
Specimen integrity:	Intact.
Tumor Features:	
Tumor site:	Upper lobe.
Tumor size:	2.0 x 1.7 x 1.5 cm.
Tumor focality:	Unifocal.
Histologic type:	Adenocarcinoma.
Histologic grade:	Grade 2 (moderately differentiated).
Lymphovascular invasion:	Identified.
Perineural invasion:	Identified.
Visceral pleural invasion:	Not identified.
Tumor extension into extra-pulmonary structures:	N/A.
Treatment effect:	N/A.
Lymph Nodes:	6/22 regional lymph nodes (peribronchial and para-aortic) positive for metastatic carcinoma.
Margin Evaluation:	
Distance to closest margin:	4.6cm (bronchial margin).
Bronchial margin:	Negative.
Vascular margin:	Negative.
Parenchymal margin:	Negative.
Parietal pleural margin:	N/A.
Chest wall margin:	N/A.
Other margins:	N/A.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT1a.
Regional lymph nodes (pN):	pN2.
Distant metastasis (pM):	pMX.
Margin status (R):	R0 (negative).
Pathologic stage:	IIIA.
Additional pathologic findings:	N/A.
Comment:	N/A.

[page 4 of 6]
FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Lung; Left Upper Lobe Wedge
- B. Lung; Left Upper Lobe For Bronchial Margins
- C. N6 #1
- D. N10L
- E. N11L
- F. N6 #2
- G. N5
- H. N9L
- I. N7
- J. N5 #2

Clinical History/Operative Dx:

Left lung nodule

Intraoperative Diagnosis:

- A. Left upper lobe wedge biopsy: Non-small cell carcinoma.
- B. Left upper lobe lung, lobectomy: Bronchial margin free of tumor. Enlarged peribronchial node positive for metastatic carcinoma by touch prep. The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

Gross Description:

A. The specimen is labeled left upper lobe lung wedge and is received without fixative. It consists of a wedge resection of lung which measures 5.2 x 2.5 x 1 cm. A metallic staple line is present along one edge. It weighs 9 grams. The pleural surface varies from dark reddish-violet to several foci which have an anthracotic appearance. There is a palpable subpleural mass centrally with very slight puckering of the pleural surface. On sectioning, this subpleural mass is tan and anthracotic and measures 2 x 1.7 x 1.5 cm. It is grossly 0.6 cm from the closest staple line. A representative section of this subpleural mass is submitted for frozen section as FS1. The tissue remaining from frozen section is submitted for permanent section in cassette A1. The staple line from the lung wedge is dissected free and the resected edge is inked green. Additional representative sections of the lung wedge, to include all the grossly recognizable neoplasm, are submitted in cassettes A2-A4. [REDACTED]

B. The specimen is labeled left upper lobe and is received without fixative. It consists of a lobe of lung [REDACTED]

[page 5 of 6]
FINAL SURGICAL PATHOLOGY REPORT

which weighs 189 grams. It measures 23.5 x 9 x up to 3 cm. The pleural surface of the lung varies from pale red to violet to tan in the basilar and most apical portion. There is anthracotic streaking which appears linear. Along the middle anterior surface of the lung, there is a 9 cm staple line. The pleural surface appears smooth throughout. At the hilum, the bronchial margin is removed as a thin shave and is submitted for frozen section as FS2. There is a prominent firm 1.1 cm peribronchial node which is also submitted for frozen section as FS3. There are two smaller 0.7-0.8 cm peribronchial nodes. The bronchi are dissected and there is no grossly obvious intrabronchial tumor. On sectioning, the metallic staple line is 4 cm from the bronchial resection margin. Sections of the pulmonary parenchyma along the staple line reveal no grossly obvious tumor. Close serial sectioning of the lung reveal the pulmonary parenchyma at the apical portion of the lung to have a honeycomb appearance. Sections of the remainder of the lung reveal spongy soft red pulmonary parenchyma without additional masses. Representative sections are submitted. Section summary: B1) bronchial margin remaining from frozen section, B2) peribronchial node remaining from frozen section, B3) vascular margin, B4) two additional peribronchial nodes, B5-B6) sections of pulmonary parenchyma along staple line, B7) representative sections of apical upper lobe, B8) representative mid lung, B9) basilar lung [REDACTED]

C. The specimen is labeled N6#1 and is received in formalin. It consists of a single slightly disrupted fragment of tan to anthracotic tissue measuring 2 x 0.7 x 0.7 cm. The specimen is serially sectioned perpendicular to the long axis and is entirely submitted in cassette C1 [REDACTED]

D. The specimen is labeled N10L and is received in formalin. It consists of a 1.2 x 0.7 x 0.3 cm fragment of fibrofatty and brown to black anthracotic appearing tissue. It is serially sectioned and entirely submitted in cassette D1 [REDACTED]

E. The specimen is labeled N11L and is received in formalin. It consists of a single 0.6 x 0.4 x 0.4 cm fragment of anthracotic tissue. It is trisected and submitted in cassette E1. [REDACTED]

F. The specimen is labeled N6#2 and is received in formalin. It consists of a 1.8 x 0.7 x 0.6 cm fragment of fibrofatty tissue. On dissection, it contains two 0.5-0.7 cm fragments of tan to anthracotic tissue. The larger fragment is inked. It is bisected and combined with the remaining tissue in cassette F1. [REDACTED]

G. The specimen is labeled N5 and is received in formalin. It consists of two fragments of lobulated fibrofatty tissue which are 2 cm in aggregate. On dissection, there are two 0.7-0.8 cm possible focally anthracotic lymph nodes. The nodes are submitted in cassette G1. [REDACTED]

H. The specimen is labeled N9L and is received in formalin. It consists of three 0.6-0.9 cm fragments of fibrofatty tissue. The largest fragment contains a 0.6 cm partially anthracotic possible node. There are two small 0.2 cm foci of anthracotic discoloration of the second largest fragment. The third fragment contains a 0.2 cm area of gray-tan anthracotic discoloration. The largest fragment including the node is inked, bisected, and combined with the remaining tissue in cassette H1 [REDACTED]

I. The specimen is labeled N7 and is received in formalin. It consists of five fragments of pale red to gray-tan anthracotic tissue. The largest fragment is 1.4 cm in maximum dimension and contains two [REDACTED]

[page 6 of 6]
FINAL SURGICAL PATHOLOGY REPORT

discrete possible anthracotic nodes. The largest fragment is dissected and the two recovered nodes are bivalved and submitted in cassette I1 (one inked). The remaining fragments are submitted intact in cassette I2. [REDACTED]

J. The specimen is labeled N5#2 and is received in formalin. It consists of two 0.8 cm fragments of fibrofatty and focally anthracotic tissue. The tissue is submitted intact in cassette J1. [REDACTED]

Microscopic Description:

- A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- G. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- H. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- I. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
- J. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.
-

Source: NCI Genomic Data Commons file cdd99d6a-6126-4357-889e-5157b2def890 (TCGA-55-7727.1E6155D1-E9EB-447D-951E-3B81F6D41156.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).